Somatic mutation profile of tumor specimen TCGA-24-1551-01A (aliquot TCGA-24-1551-01A-01W-0551-08) from TCGA case TCGA-24-1551, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 53.8 years (19,661 days).
Specimen TCGA-24-1551-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 001debde-6fcf-4691-a7de-a28bbd40daa8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1551-10A (Blood Derived Normal), aliquot TCGA-24-1551-10A-01W-0551-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39d7746e-f7fa-438e-90a5-af9595c1cacf

The open-access MAF lists 52 somatic variants for this specimen: 38 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 12, Intron 1, Frame Shift Ins 1, 3'UTR 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A1 | c.2085dup p.G696Rfs*6 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | catalogued as rs606231464; ClinVar: pathogenic; called by pindel, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 490/633 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AASDHPPT | c.173A>G p.K58R | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV53788822; called by muse, mutect2, varscan2
- ADAMTS16 | c.3509C>T p.S1170L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs762838325, COSV56985201; called by muse, mutect2, varscan2
- AMOTL1 | c.1032G>C p.E344D | Missense Mutation (SNP) | VAF 286/1169 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV54415055; called by muse, mutect2, varscan2
- C19orf53 | c.21G>C p.K7N | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50004117; called by muse, mutect2
- C19orf53 | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 182/320 reads (57%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.835); catalogued as rs183989129, COSV55605987; called by muse, mutect2, varscan2
- CDK12 | c.2964-1G>C p.X988_splice | Splice Site (SNP) | VAF 629/776 reads (81%) | catalogued as COSV71003513; called by muse, mutect2, varscan2
- CSF2RB | c.2299G>T p.V767L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53256947; called by muse, mutect2, varscan2
- CYTH2 | c.313G>T p.G105W | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57309157; called by muse, mutect2, varscan2
- EIF3I | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.095); catalogued as COSV59084304; called by muse, mutect2, varscan2
- FAM120C | c.2988A>T p.K996N | Missense Mutation (SNP) | VAF 143/321 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as COSV60258679; called by muse, mutect2, varscan2
- FAT3 | c.3664C>A p.L1222M | Missense Mutation (SNP) | VAF 54/209 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99972639; called by muse, mutect2, varscan2
- FBXW11 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 198/454 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs1407753498, COSV51608348; called by muse, mutect2, varscan2
- GAB2 | c.992C>A p.T331N (on ENST00000361507 / NM_080491.3; = p.T293N on NM_012296.3) | Missense Mutation (SNP) | VAF 61/281 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV60867100; called by muse, mutect2, varscan2
- GNAL | c.275C>G p.T92R (on ENST00000269162 / NM_001142339.3; = p.T169R on NM_182978.4) | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99304397; called by muse, mutect2, varscan2
- HCN4 | c.2341C>G p.P781A | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56082718; called by muse, mutect2, varscan2
- JRKL | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 16/537 reads (3%) | SIFT tolerated (0.68); PolyPhen benign (0.067); catalogued as COSV99567638; called by muse, mutect2
- KLHL14 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.682); catalogued as COSV100839335, COSV63835286; called by muse, mutect2, varscan2
- L1CAM | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as COSV62827668; called by muse, mutect2, varscan2
- MAGEB3 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0.049); catalogued as rs761710997, COSV100854844; called by muse, mutect2, varscan2
- MOGAT3 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV56173812; called by muse, mutect2, varscan2
- NETO1 | c.721A>T p.S241C | Missense Mutation (SNP) | VAF 319/377 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55004815; called by muse, mutect2, varscan2
- PRAMEF19 | c.360G>T p.R120S | Missense Mutation (SNP) | VAF 235/2080 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.055); catalogued as rs1366277646; called by muse, mutect2, varscan2
- RTL6 | c.631T>C p.S211P | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100373903; called by mutect2, varscan2
- SDHA | c.1012G>C p.A338P | Missense Mutation (SNP) | VAF 21/344 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99372346; called by muse, mutect2
- SIK3 | c.1978C>T p.R660C (on ENST00000445177 / NM_001366686.2; = p.R618C on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 1161/1576 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1430574837, COSV52612435; called by muse, mutect2, varscan2
- SLCO2A1 | c.1409G>A p.C470Y | Missense Mutation (SNP) | VAF 261/895 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100189519; called by muse, mutect2, varscan2
- SNAI3 | c.593T>C p.L198P | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60002577; called by muse, mutect2, varscan2
- TLL2 | c.338A>C p.D113A | Missense Mutation (SNP) | VAF 166/444 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0.014); catalogued as COSV63571825; called by muse, mutect2, varscan2
- TRUB2 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100306873; called by muse, mutect2, varscan2
- WDR82 | c.387G>C p.K129N | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV56601455; called by muse, mutect2, varscan2
- WDR91 | c.1199G>C p.G400A | Missense Mutation (SNP) | VAF 46/315 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV60369325; called by muse, mutect2, varscan2
- XYLB | c.1600C>A p.P534T | Missense Mutation (SNP) | VAF 188/466 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs147529368, COSV99264622; called by muse, mutect2, varscan2
- ZNF112 | c.2675A>G p.E892G (on ENST00000337401 / NM_001083335.2; = p.E886G on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/234 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV61619596; called by muse, mutect2, varscan2
- ZNF518A | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV60151055; called by muse, mutect2, varscan2
- ZNF7 | c.996G>T p.R332S | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV57383251; called by muse, mutect2, varscan2
- POFUT1 | c.1015_1034del p.V339Pfs*38 | Frame Shift Del (DEL) | VAF 86/505 reads (17%) | called by mutect2, pindel
- ADGRE1 | c.2601C>A p.S867= | Silent (SNP) | VAF 115/288 reads (40%) | catalogued as COSV51674486; called by muse, mutect2, varscan2
- AKAP11 | c.855T>C p.S285= | Silent (SNP) | VAF 66/88 reads (75%) | catalogued as rs147436453, COSV50295544; called by muse, mutect2, varscan2
- ARMCX2 | c.915C>T p.D305= | Silent (SNP) | VAF 211/523 reads (40%) | catalogued as rs1556057070, COSV57529701; called by muse, mutect2, varscan2
- CYP21A2 | c.84C>T p.L28= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV64477226; called by muse, mutect2, varscan2
- FAT3 | c.3663T>C p.F1221= | Silent (SNP) | VAF 52/209 reads (25%) | catalogued as COSV99972634; called by muse, mutect2, varscan2
- FBXO46 | c.1536G>A p.V512= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as rs1329618476, COSV58348315; called by muse, mutect2, varscan2
- GFRA3 | c.1071C>T p.S357= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV99218604; called by muse, mutect2
- MAGEA11 | c.711T>C p.Y237= | Silent (SNP) | VAF 74/196 reads (38%) | catalogued as rs781931658, COSV100290772; called by muse, mutect2, varscan2
- RTL6 | c.45A>G p.A15= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as rs1321706396, COSV57979511; called by muse, varscan2
- SPATC1 | c.492C>T p.T164= | Silent (SNP) | VAF 5/8 reads (63%) | catalogued as rs1245370458, COSV66298585; called by muse, mutect2, varscan2
- TRRAP | c.6000C>T p.I2000= (on ENST00000359863 / NM_001244580.1; = p.I1982= on NM_003496.3) | Silent (SNP) | VAF 82/226 reads (36%) | catalogued as rs782365110, COSV62842582; called by muse, mutect2, varscan2
- ZCWPW2 | c.198A>G p.S66= | Silent (SNP) | VAF 22/250 reads (9%) | catalogued as COSV67498355; called by muse, mutect2
- ADARB2 | c.101-177536G>A | Intron (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- PLK1 | c.*2A>C | 3'UTR (SNP) | VAF 22/51 reads (43%) | catalogued as COSV99892725; called by muse, mutect2, varscan2
